Somatic mutation profile of tumor specimen C3L-00369-03 (aliquot CPT0006520009) from CPTAC case C3L-00369, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 90 years or older (exact value withheld by GDC).
Specimen C3L-00369-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 371e5579-920b-4c8b-9ee8-828de158c27e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00369-31 (Blood Derived Normal), aliquot CPT0002660002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66523ea2-17da-4487-b64c-43d4b16e8272

The open-access MAF lists 105 somatic variants for this specimen: 71 protein-altering or splice-affecting, 16 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 16, Intron 12, Frame Shift Ins 4, Frame Shift Del 3, Splice Region 3, Nonsense Mutation 2, RNA 2, 5'Flank 2, 3'UTR 1, 3'Flank 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC9 | c.3246G>T p.R1082S | Missense Mutation (SNP) | VAF 70/250 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1380107048; called by muse, mutect2, varscan2
- ADSS1 | c.197dup p.X66_splice | Splice Site (INS) | VAF 41/117 reads (35%) | catalogued as rs760706338; called by mutect2, pindel, varscan2
- ANGPTL1 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 99/297 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0.146); catalogued as COSV52367273; called by muse, mutect2, varscan2
- AOC1 | c.1499G>A p.R500H | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.17); PolyPhen benign (0.046); catalogued as rs759480873, COSV62870757; called by muse, mutect2, varscan2
- CCT2 | c.194A>G p.N65S | Missense Mutation (SNP) | VAF 74/212 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs780624649; called by muse, mutect2, varscan2
- CUX2 | c.82G>A p.A28T | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs374906688; called by muse, mutect2, varscan2
- DNMT3A | c.1543C>T p.Q515* | Nonsense Mutation (SNP) | VAF 46/145 reads (32%) | catalogued as rs1449820788, COSV53051427; called by muse, mutect2, varscan2
- FMNL3 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs1420812239, COSV99526824; called by muse, mutect2, varscan2
- GP9 | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 186/561 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.116); catalogued as rs745846700, COSV100264665; called by muse, mutect2, varscan2
- GPR174 | c.68C>A p.A23E | Missense Mutation (SNP) | VAF 54/69 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99338376; called by muse, mutect2, varscan2
- KIF4B | c.1955G>A p.R652H | Missense Mutation (SNP) | VAF 164/494 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as rs199820075, COSV101469192, COSV70526998; called by muse, mutect2, varscan2
- NCAM2 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 52/124 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.874); catalogued as rs201907310, COSV53103643; called by mutect2, varscan2
- NEU4 | c.43C>T p.R15W (on ENST00000391969 / NM_001167602.3; = p.R27W on NM_080741.4) | Missense Mutation (SNP) | VAF 97/283 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1430494348; called by muse, mutect2, varscan2
- POLQ | c.3697G>A p.V1233I | Missense Mutation (SNP) | VAF 55/131 reads (42%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.005); catalogued as rs1560097578; called by muse, mutect2, varscan2
- SIGLEC6 | c.1168G>A p.V390I | Missense Mutation (SNP) | VAF 96/229 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.121); catalogued as rs563918580, COSV58434842; called by muse, mutect2, varscan2
- TMEM132C | c.2536G>A p.V846M | Missense Mutation (SNP) | VAF 80/174 reads (46%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs780371502; called by muse, mutect2, varscan2
- TOGARAM2 | c.2356G>A p.V786M | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs757227797; called by muse, mutect2, varscan2
- TTN | c.93650A>C p.K31217T (on ENST00000591111; = p.K23793T on NM_003319.4) | Missense Mutation (SNP) | VAF 91/253 reads (36%) | PolyPhen possibly damaging (0.801); catalogued as rs1322355821; called by muse, mutect2, varscan2
- VHL | c.512del p.K171Sfs*31 | Frame Shift Del (DEL) | VAF 221/412 reads (54%) | catalogued as COSV56544879; called by mutect2, pindel, varscan2
- YIPF5 | c.243C>G p.F81L | Missense Mutation (SNP) | VAF 113/267 reads (42%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV50823145; called by muse, mutect2, varscan2
- ADAMTS20 | c.2273C>G p.P758R | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.331); called by muse, mutect2, varscan2
- AGBL4 | c.773G>T p.R258L | Missense Mutation (SNP) | VAF 96/271 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ALMS1 | c.1646A>C p.E549A | Missense Mutation (SNP) | VAF 68/223 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- ARHGAP30 | c.566A>C p.N189T | Missense Mutation (SNP) | VAF 119/337 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.3917_3918dup p.N1307* | Frame Shift Ins (INS) | VAF 99/310 reads (32%) | called by mutect2, pindel, varscan2
- BSPRY | c.793G>T p.G265C | Missense Mutation (SNP) | VAF 138/355 reads (39%) | SIFT tolerated (0.24); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- CARMIL2 | c.1824T>G p.N608K | Missense Mutation (SNP) | VAF 139/402 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- CCDC114 | c.156del p.L53Wfs*8 | Frame Shift Del (DEL) | VAF 89/321 reads (28%) | called by mutect2, pindel, varscan2
- CEBPA | c.865C>A p.R289S | Missense Mutation (SNP) | VAF 229/559 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFAP44 | c.155C>T p.T52I | Missense Mutation (SNP) | VAF 76/274 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); called by muse, mutect2
- CHD9 | c.7657A>C p.N2553H (on ENST00000398510 / NM_001382353.1; = p.N2537H on NM_025134.7) | Missense Mutation (SNP) | VAF 88/231 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CLUL1 | c.1294T>G p.F432V | Missense Mutation (SNP) | VAF 59/195 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CNOT7 | c.791C>A p.S264Y | Missense Mutation (SNP) | VAF 63/107 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- DHRS4 | c.74C>G p.T25S | Missense Mutation (SNP) | VAF 90/359 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DMGDH | c.1620_1621dup p.N541Ifs*28 | Frame Shift Ins (INS) | VAF 42/162 reads (26%) | called by mutect2, varscan2
- DNAH14 | c.9239T>G p.I3080S (on ENST00000445597; = p.I4088S on NM_001367479.1) | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- DOCK9 | c.190A>C p.I64L (on ENST00000376460 / NM_001366676.2; = p.I65L on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT tolerated (0.53); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- DOT1L | c.1045A>G p.S349G | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EBF3 | c.154del p.A52Rfs*80 | Frame Shift Del (DEL) | VAF 53/153 reads (35%) | called by mutect2, pindel, varscan2
- ELAC2 | c.404A>C p.K135T | Missense Mutation (SNP) | VAF 99/317 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- FAHD1 | c.188C>G p.A63G | Missense Mutation (SNP) | VAF 23/120 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FHAD1 | c.1626G>T p.Q542H | Missense Mutation (SNP) | VAF 56/203 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GANC | c.1606dup p.E536Gfs*26 | Frame Shift Ins (INS) | VAF 74/228 reads (32%) | called by mutect2, pindel, varscan2
- GTF2I | c.1750+9_1750+10dup | Splice Region (INS) | VAF 23/224 reads (10%) | called by mutect2, pindel, varscan2
- MAML1 | c.1802C>T p.S601F | Missense Mutation (SNP) | VAF 253/649 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- MAPK1IP1L | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 72/170 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- MTHFS | c.508A>G p.T170A | Missense Mutation (SNP) | VAF 230/652 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- NEK5 | c.1753T>A p.L585I | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.569); called by muse, mutect2, varscan2
- NLRP1 | c.2264C>T p.T755I | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- OBSCN | c.12542A>G p.E4181G | Missense Mutation (SNP) | VAF 20/399 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- OR3A2 | c.772_774del p.C258del | In Frame Del (DEL) | VAF 61/216 reads (28%) | called by mutect2, pindel, varscan2
- PITRM1 | c.2531_2532insCAC p.M844delinsIT | Splice Region (INS) | VAF 38/134 reads (28%) | called by mutect2, varscan2
- PITRM1 | c.2527_2529dup p.V843dup | In Frame Ins (INS) | VAF 36/146 reads (25%) | called by mutect2*, pindel, varscan2*
- PKHD1L1 | c.2368T>G p.Y790D | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PLCD1 | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 148/224 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- RAB3GAP1 | c.1557G>A p.M519I | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SAMD10 | c.365A>C p.D122A | Missense Mutation (SNP) | VAF 26/478 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); called by muse, mutect2
- SH2D4B | c.1261C>A p.Q421K (on ENST00000646907; = p.T346K on NM_207372.2) | Missense Mutation (SNP) | VAF 84/292 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SH3TC1 | c.341A>C p.E114A | Missense Mutation (SNP) | VAF 78/246 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SMARCA2 | c.2261G>C p.G754A | Missense Mutation (SNP) | VAF 46/290 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SMTNL2 | c.1221G>T p.Q407H (on ENST00000389313 / NM_001114974.2; = p.Q263H on NM_198501.3) | Missense Mutation (SNP) | VAF 92/242 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- SNAI1 | c.241G>T p.E81* | Nonsense Mutation (SNP) | VAF 74/155 reads (48%) | called by muse, mutect2, varscan2
- TDRD10 | c.932A>T p.Q311L | Missense Mutation (SNP) | VAF 59/174 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TRAP1 | c.491C>A p.T164K | Missense Mutation (SNP) | VAF 60/198 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- USP24 | c.2935A>G p.S979G | Missense Mutation (SNP) | VAF 107/247 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- USP53 | c.596G>A p.R199K | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- VGF | c.1604A>T p.D535V | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- WDR87 | c.129G>A p.Q43= | Splice Region (SNP) | VAF 88/233 reads (38%) | called by muse, mutect2, varscan2
- ZDBF2 | c.3347dup p.L1116Ffs*6 | Frame Shift Ins (INS) | VAF 44/181 reads (24%) | called by mutect2, pindel, varscan2
- ZFP28 | c.997T>A p.S333T | Missense Mutation (SNP) | VAF 63/174 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZNF677 | c.850A>T p.I284F | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ATG13 | c.1218T>C p.D406= (on ENST00000359513 / NM_001346321.1; = p.D369= on NM_014741.4 and 9 other RefSeq transcripts) | Silent (SNP) | VAF 88/266 reads (33%) | called by muse, mutect2, varscan2
- BTBD18 | c.495C>A p.T165= | Silent (SNP) | VAF 97/269 reads (36%) | called by muse, mutect2, varscan2
- C5orf15 | c.69C>T p.I23= | Silent (SNP) | VAF 204/527 reads (39%) | catalogued as rs747208047, COSV51548789; called by muse, mutect2, varscan2
- COL6A3 | c.9402C>T p.T3134= | Silent (SNP) | VAF 78/213 reads (37%) | called by muse, mutect2, varscan2
- IPO9 | c.2154G>A p.R718= | Silent (SNP) | VAF 7/177 reads (4%) | called by muse, mutect2
- KLHL17 | c.1887G>T p.P629= | Silent (SNP) | VAF 133/295 reads (45%) | called by muse, mutect2, varscan2
- MROH2B | c.808A>C p.R270= | Silent (SNP) | VAF 35/133 reads (26%) | called by muse, mutect2, varscan2
- MYH13 | c.1755C>T p.A585= | Silent (SNP) | VAF 115/302 reads (38%) | catalogued as rs1040817237; called by muse, mutect2, varscan2
- NCKAP1L | c.2091C>G p.S697= | Silent (SNP) | VAF 67/207 reads (32%) | called by muse, mutect2, varscan2
- NEB | c.2985G>A p.S995= | Silent (SNP) | VAF 32/198 reads (16%) | catalogued as rs574544074; called by muse, mutect2, varscan2
- OBSCN | c.21501G>A p.R7167= | Silent (SNP) | VAF 83/220 reads (38%) | called by muse, mutect2
- PKP3 | c.118C>A p.R40= | Silent (SNP) | VAF 132/337 reads (39%) | catalogued as rs1052027375; called by muse, mutect2, varscan2
- RAB6A | c.411A>T p.S137= | Silent (SNP) | VAF 81/199 reads (41%) | called by muse, mutect2, varscan2
- TEKT5 | c.771C>T p.S257= | Silent (SNP) | VAF 32/111 reads (29%) | called by muse, mutect2, varscan2
- TUSC1 | c.318G>A p.E106= | Silent (SNP) | VAF 20/421 reads (5%) | called by muse, mutect2
- VN1R5 | c.915G>A p.Q305= | Silent (SNP) | VAF 163/413 reads (39%) | called by muse, mutect2, varscan2
- ABCA11P | n.942T>G | RNA (SNP) | VAF 166/507 reads (33%) | called by muse, mutect2, varscan2
- ALDH1L1 | c.858+35A>G | Intron (SNP) | VAF 201/530 reads (38%) | called by muse, mutect2, varscan2
- ANKRD11 | c.-59-7292G>T | Intron (SNP) | VAF 35/95 reads (37%) | called by muse, mutect2, varscan2
- FAM160A2 | c.2215+211G>T | Intron (SNP) | VAF 115/296 reads (39%) | called by muse, mutect2, varscan2
- LEO1 | c.1896+11dup | Intron (INS) | VAF 118/348 reads (34%) | called by mutect2, pindel, varscan2
- MEAK7 | c.153+453C>A | Intron (SNP) | VAF 42/95 reads (44%) | called by muse, mutect2, varscan2
- MIOX | c.341-11C>G | Intron (SNP) | VAF 43/130 reads (33%) | called by muse, mutect2, varscan2
- NPIPA7 | chr16:16374438 G>A | 5'Flank (SNP) | VAF 86/509 reads (17%) | catalogued as rs757063145; called by muse, mutect2, varscan2
- NPIPA7 | chr16:16374439 C>T | 5'Flank (SNP) | VAF 86/514 reads (17%) | catalogued as rs1370785882; called by muse, mutect2, varscan2
- PLCXD2 | c.*19A>T | 3'UTR (SNP) | VAF 35/98 reads (36%) | called by muse, mutect2, varscan2
- POLR3E | c.87+235G>T | Intron (SNP) | VAF 90/258 reads (35%) | called by muse, mutect2, varscan2
- POM121 | chr7:72948675 T>C | 3'Flank (SNP) | VAF 120/496 reads (24%) | catalogued as rs1044877; called by muse, mutect2, varscan2
- RAB21 | c.220-37_220-33del | Intron (DEL) | VAF 63/198 reads (32%) | called by mutect2, pindel, varscan2
- TCF4 | c.305-168T>C | Intron (SNP) | VAF 82/210 reads (39%) | called by muse, mutect2, varscan2
- TNFRSF1B | c.308-26C>G | Intron (SNP) | VAF 156/358 reads (44%) | called by muse, mutect2, varscan2
- TPM1 | c.564-34T>C | Intron (SNP) | VAF 165/433 reads (38%) | called by muse, mutect2, varscan2
- USP32 | c.1239+4501C>T | Intron (SNP) | VAF 46/119 reads (39%) | catalogued as COSV100343230; called by muse, mutect2, varscan2
- XIST | n.8559T>A | RNA (SNP) | VAF 110/142 reads (77%) | called by muse, mutect2, varscan2
